Somatic mutation profile of tumor specimen ALCH-AEKQ-TTR1-A (aliquot ALCH-AEKQ-TTR1-A-1-0-D-A777-36) from ALCHEMIST case ALCH-AEKQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 73.8 years (26,969 days).
Specimen ALCH-AEKQ-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5974ff30-e69d-4dc4-9ac7-d5d329b6a2ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEKQ-NB1-A (Blood Derived Normal), aliquot ALCH-AEKQ-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4650a4d6-7ad1-46a0-82da-86a0e72dab92

The open-access MAF lists 593 somatic variants for this specimen: 381 protein-altering or splice-affecting, 140 silent, 72 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 317, Silent 140, Intron 30, Nonsense Mutation 24, Frame Shift Del 21, RNA 12, 5'Flank 11, Splice Site 9, 5'UTR 9, 3'UTR 7, Frame Shift Ins 5, Splice Region 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 58/576 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.11394T>G p.S3798R | Missense Mutation (SNP) | VAF 69/213 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV101446895; called by muse, mutect2, varscan2
- ABCB11 | c.3123T>A p.Y1041* | Nonsense Mutation (SNP) | VAF 60/250 reads (24%) | catalogued as CM103539; called by muse, mutect2, varscan2
- ADAMDEC1 | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV99836254; called by muse, mutect2, varscan2
- ADCY6 | c.3284G>T p.G1095V | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1212371539; called by muse, mutect2, varscan2
- ADCY9 | c.1772T>C p.F591S | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV53577043; called by muse, mutect2, varscan2
- AKAP4 | c.2092G>C p.D698H | Missense Mutation (SNP) | VAF 52/380 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62073830; called by muse, varscan2
- AKAP4 | c.2004C>G p.N668K | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782020421; called by muse, varscan2
- APOA5 | c.844del p.R282Afs*15 | Frame Shift Del (DEL) | VAF 163/527 reads (31%) | catalogued as CM151061; called by mutect2, pindel, varscan2
- ARHGEF40 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs114773484; called by muse, mutect2, varscan2
- ARNTL2 | c.1166C>T p.T389I | Missense Mutation (SNP) | VAF 61/92 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1356276485, COSV99668280; called by muse, mutect2, varscan2
- ASXL3 | c.436G>C p.V146L | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.136); catalogued as rs372776497; called by muse, mutect2, varscan2
- ASXL3 | c.3562C>G p.P1188A | Missense Mutation (SNP) | VAF 77/279 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.006); catalogued as COSV52476118, COSV52478641; called by muse, mutect2, varscan2
- ATP2C2 | c.974C>T p.T325M | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs370823582; called by muse, mutect2, varscan2
- BTD | c.1331G>T p.G444V | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV100329407; called by muse, mutect2, varscan2
- C19orf33 | c.285G>C p.K95N | Missense Mutation (SNP) | VAF 138/194 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); catalogued as COSV56651710; called by muse, mutect2, varscan2
- CA5BP1 | n.228G>C | Splice Region (SNP) | VAF 289/395 reads (73%) | catalogued as rs998633110; called by muse, mutect2, varscan2
- CACNA1A | c.7223del p.P2408Rfs*206 (on ENST00000614285; = p.P2408Rfs*? on NM_023035.3) | Frame Shift Del (DEL) | VAF 9/83 reads (11%) | catalogued as rs1434850038; called by mutect2, pindel
- CASP8AP2 | c.4458G>C p.E1486D | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1359310204, COSV99386661; called by muse, mutect2, varscan2
- CCDC85C | c.632C>G p.A211G | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV66549988; called by muse, mutect2, varscan2
- CHGB | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as rs1342437688; called by muse, mutect2, varscan2
- CHST1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.202); catalogued as rs1256615836; called by muse, mutect2, varscan2
- COL24A1 | c.1630G>T p.G544C | Missense Mutation (SNP) | VAF 103/401 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100992948; called by muse, mutect2, varscan2
- DAZL | c.469A>G p.T157A | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs915248084; called by muse, mutect2, varscan2
- DCAF4L2 | c.1002G>T p.Q334H | Missense Mutation (SNP) | VAF 74/118 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100150553; called by muse, mutect2, varscan2
- DISP1 | c.2242G>T p.E748* | Nonsense Mutation (SNP) | VAF 429/871 reads (49%) | catalogued as COSV99452467; called by muse, mutect2, varscan2
- DOCK6 | c.2045C>A p.P682Q | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs578208057; called by muse, mutect2, varscan2
- DPPA5 | c.7A>T p.T3S | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV64875917; called by muse, mutect2, varscan2
- DVL3 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 26/334 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs781210884; called by muse, mutect2
- EPHB2 | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs759303586; called by muse, mutect2, varscan2
- F5 | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 100/572 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63124742; called by muse, mutect2, varscan2
- FGF10 | c.522G>T p.R174S | Missense Mutation (SNP) | VAF 122/819 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV52934376; called by muse, mutect2, varscan2
- GLRB | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 84/86 reads (98%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs868572342; called by muse, mutect2, varscan2
- GRIN2A | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 139/686 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1555491654, COSV100410478; called by muse, mutect2, varscan2
- HAO2 | c.1035G>T p.L345F | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.756); catalogued as COSV58037661; called by muse, mutect2, varscan2
- HDAC6 | c.509C>A p.T170N | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.511); catalogued as rs1282852708; called by muse, mutect2, varscan2
- IFNG | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 74/422 reads (18%) | catalogued as rs767503659; called by muse, mutect2, varscan2
- IGKV1-17 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 50/377 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs548975894; called by muse, varscan2
- IGKV1D-17 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 70/373 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs928824182; called by muse, mutect2, varscan2
- IL23R | c.726G>A p.W242* | Nonsense Mutation (SNP) | VAF 76/301 reads (25%) | catalogued as COSV61375912; called by muse, mutect2, varscan2
- IL6ST | c.2375G>A p.R792Q | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as rs776416568; called by muse, mutect2, varscan2
- IMPG2 | c.2224A>G p.I742V | Missense Mutation (SNP) | VAF 140/305 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV51973642; called by muse, mutect2, varscan2
- JAKMIP1 | c.1459C>A p.R487S | Missense Mutation (SNP) | VAF 98/203 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51545691; called by muse, mutect2, varscan2
- KCNJ11 | c.100C>A p.R34S | Missense Mutation (SNP) | VAF 101/105 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM074294; called by muse, mutect2, varscan2
- KIF2B | c.1289A>G p.Q430R | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV52135970; called by muse, mutect2, varscan2
- KIT | c.2882G>A p.G961D | Missense Mutation (SNP) | VAF 340/687 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1334133798; called by muse, varscan2
- LILRA4 | c.998C>A p.T333K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.519); catalogued as rs141838994; called by muse, mutect2, varscan2
- LRP1 | c.6421C>T p.Q2141* | Nonsense Mutation (SNP) | VAF 38/155 reads (25%) | catalogued as COSV54505830; called by muse, mutect2, varscan2
- MAPK1 | c.725-1G>T p.X242_splice | Splice Site (SNP) | VAF 44/64 reads (69%) | catalogued as COSV53187454; called by muse, varscan2
- MCOLN2 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs377754033; called by muse, mutect2, varscan2
- MEF2D | c.261C>A p.T87= | Splice Region (SNP) | VAF 45/157 reads (29%) | catalogued as COSV61730386; called by muse, mutect2, varscan2
- MNAT1 | c.242+1G>T p.X81_splice | Splice Site (SNP) | VAF 54/77 reads (70%) | catalogued as rs768740616; called by muse, mutect2, varscan2
- MROH6 | c.950G>A p.G317D | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.732); catalogued as rs1312426834; called by muse, mutect2, varscan2
- MYOD1 | c.349C>A p.R117S | Missense Mutation (SNP) | VAF 59/60 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100000232; called by muse, mutect2, varscan2
- NDNF | c.393T>A p.N131K | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101113182; called by muse, mutect2, varscan2
- NLGN4X | c.2150C>A p.T717N | Missense Mutation (SNP) | VAF 82/526 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.127); catalogued as rs1398505989; called by muse, mutect2, varscan2
- NLRP12 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.329); catalogued as COSV60750759; called by muse, mutect2
- NOTCH3 | c.3920C>G p.T1307R | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.938); catalogued as COSV54631793; called by muse, mutect2, varscan2
- OBSCN | c.14831A>C p.H4944P | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV52817589; called by muse, mutect2, varscan2
- OR10T2 | c.5G>A p.R2Q | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs749324831, COSV100554849; called by muse, varscan2
- OR2L3 | c.444G>T p.W148C | Missense Mutation (SNP) | VAF 177/301 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63455742, COSV63456116; called by muse, mutect2, varscan2
- OR2M4 | c.816G>T p.K272N | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as COSV60707445; called by muse, mutect2, varscan2
- OR4K1 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 127/728 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53460010; called by muse, mutect2, varscan2
- OR5M11 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 196/350 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73141978; called by muse, mutect2, varscan2
- OR6C3 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 50/228 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.589); catalogued as rs866375503, COSV65570631; called by muse, mutect2, varscan2
- OTOP2 | c.1360C>T p.L454F | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as rs1461633323; called by muse, mutect2, varscan2
- PCDH15 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 104/262 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57403315; called by muse, mutect2, varscan2
- PCDHGA6 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 69/75 reads (92%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.049); catalogued as COSV54020507; called by muse, mutect2, varscan2
- PCDHGA6 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 56/66 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.405); catalogued as rs1385892757; called by mutect2, varscan2
- PDGFD | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 142/456 reads (31%) | catalogued as rs1373391412; called by muse, mutect2, varscan2
- POMT2 | c.665C>G p.S222C | Missense Mutation (SNP) | VAF 253/348 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs911038793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP2R2B | c.1190del p.G397Afs*31 (on ENST00000394409; = p.G463Afs*31 on NM_181674.2) | Frame Shift Del (DEL) | VAF 206/346 reads (60%) | catalogued as rs767808084; called by pindel, varscan2
- PRICKLE3 | c.490C>G p.R164G | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66235172; called by muse, mutect2, varscan2
- PTPRN2 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 117/197 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV67059806; called by muse, mutect2, varscan2
- RBM43 | c.796G>T p.V266F | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as rs1421776449; called by muse, mutect2, varscan2
- RNASEL | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 155/634 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs375872977; called by muse, mutect2, varscan2
- RNGTT | c.1282A>T p.N428Y | Missense Mutation (SNP) | VAF 72/234 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV99667447; called by muse, mutect2, varscan2
- RPH3A | c.1732G>T p.A578S (on ENST00000389385 / NM_001143854.2; = p.A574S on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1180526816; called by muse, mutect2, varscan2
- SBSN | c.1314C>A p.D438E | Missense Mutation (SNP) | VAF 119/170 reads (70%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV71733350; called by muse, mutect2, varscan2
- SCN4B | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 297/556 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140348243, CM109585; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHB | c.1088C>A p.S363Y | Missense Mutation (SNP) | VAF 57/288 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.648); catalogued as rs1412375956; called by muse, mutect2, varscan2
- SLC17A3 | c.759+1G>T p.X253_splice | Splice Site (SNP) | VAF 190/338 reads (56%) | catalogued as COSV57760036; called by muse, mutect2, varscan2
- SPATA31A6 | c.1386G>A p.M462I | Missense Mutation (SNP) | VAF 251/1075 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs745969363; called by muse, mutect2, varscan2
- SPTBN1 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61689230; called by muse, mutect2, varscan2
- SSBP3 | c.420del p.S141Afs*3 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | catalogued as COSV58887464; called by mutect2, varscan2
- SSC5D | c.1615G>A p.G539R | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1191141194; called by muse, mutect2, varscan2
- SYNE1 | c.8539G>A p.D2847N (on ENST00000367255 / NM_182961.4; = p.D2854N on NM_033071.3) | Missense Mutation (SNP) | VAF 136/449 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV55133582; called by muse, mutect2, varscan2
- TMEM150B | c.16T>C p.S6P | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as rs1210077170; called by muse, mutect2, varscan2
- TMEM59L | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.132); catalogued as COSV53242194; called by muse, mutect2
- TMEM82 | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs749109111; called by muse, mutect2, varscan2
- TNK2 | c.2023G>C p.E675Q | Missense Mutation (SNP) | VAF 103/189 reads (54%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); catalogued as COSV100361566; called by muse, mutect2, varscan2
- TP53 | c.929del p.N310Tfs*35 | Frame Shift Del (DEL) | VAF 71/104 reads (68%) | catalogued as COSV52772317; called by mutect2, pindel, varscan2
- TRERF1 | c.2072G>T p.R691L | Missense Mutation (SNP) | VAF 138/238 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.167); catalogued as rs564334935; called by muse, mutect2, varscan2
- TRIB3 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 168/287 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs764336159, COSV53932394, COSV99423645; called by muse, mutect2, varscan2
- TTN | c.31157A>T p.K10386M (on ENST00000591111; = p.K9459M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/103 reads (36%) | PolyPhen probably damaging (0.997); catalogued as COSV60052796; called by muse, mutect2, varscan2
- TTN | c.24974C>A p.P8325Q (on ENST00000591111; = p.P7398Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/43 reads (67%) | PolyPhen probably damaging (0.945); catalogued as COSV100592539; called by muse, mutect2, varscan2
- UGT2A3 | c.1193T>A p.L398H | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs1199561426; called by muse, mutect2, varscan2
- VN1R4 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1212058729; called by muse, mutect2, varscan2
- ZBP1 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 55/334 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs762116149, COSV59060764, COSV59064778; called by muse, mutect2, varscan2
- ZBTB18 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs376645032; called by muse, mutect2, varscan2
- ZBTB7A | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs755220452, COSV59329695; called by muse, mutect2, varscan2
- ZIM2 | c.1318C>T p.L440F | Missense Mutation (SNP) | VAF 74/466 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.024); catalogued as COSV55625605, COSV99690046; called by muse, mutect2, varscan2
- ZNF133 | c.1574G>T p.R525L (on ENST00000316358 / NM_001352454.2; = p.R524L on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.198); catalogued as COSV60366386; called by muse, mutect2, varscan2
- ZNF248 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 142/157 reads (90%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV61997190; called by muse, mutect2, varscan2
- ZNF454 | c.1394A>G p.E465G | Missense Mutation (SNP) | VAF 66/68 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60766568; called by muse, mutect2, varscan2
- ZNF804A | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 209/314 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56447299, COSV56450959; called by muse, mutect2, varscan2
- ZNF875 | c.795G>C p.K265N | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV60991084; called by muse, mutect2
- A2ML1 | c.2276C>A p.A759D | Missense Mutation (SNP) | VAF 175/244 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- ABCA8 | c.1085G>T p.S362I | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ACOT9 | c.433G>C p.V145L | Missense Mutation (SNP) | VAF 114/156 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.242); called by muse, varscan2
- ACSL4 | c.986C>A p.A329E (on ENST00000340800 / NM_022977.2; = p.A288E on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 172/354 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAM20 | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 173/238 reads (73%) | SIFT tolerated (0.2); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ADGRF3 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADGRL3 | c.1154G>T p.C385F (on ENST00000506720 / NM_001322402.2; = p.C317F on NM_015236.6) | Missense Mutation (SNP) | VAF 127/268 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, varscan2
- AFDN | c.5472G>T p.K1824N (on ENST00000447894 / NM_001366320.1; = p.K1743N on NM_001207008.1) | Missense Mutation (SNP) | VAF 79/395 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AKR1D1 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 176/327 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANO4 | c.733C>A p.H245N (on ENST00000392977 / NM_001286615.2; = p.H210N on NM_178826.4) | Missense Mutation (SNP) | VAF 89/159 reads (56%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- AP1B1 | c.2744A>C p.Q915P | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- ARHGEF12 | c.3078G>T p.L1026F | Missense Mutation (SNP) | VAF 74/280 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- ARID2 | c.773A>T p.E258V | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ASPH | c.36C>A p.N12K | Missense Mutation (SNP) | VAF 146/189 reads (77%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ATP6AP2 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 88/513 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- AVPR1B | c.887C>A p.P296H | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BBS7 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 189/211 reads (90%) | SIFT tolerated (0.17); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- BIRC6 | c.9340A>C p.S3114R | Missense Mutation (SNP) | VAF 54/86 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- BLCAP | c.2_12del p.M1_?4 | Frame Shift Del (DEL) | VAF 36/72 reads (50%) | called by mutect2, pindel, varscan2
- BRCA2 | c.5515G>T p.V1839L | Missense Mutation (SNP) | VAF 90/96 reads (94%) | SIFT tolerated (0.29); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CACNA1C | c.5391del p.L1798Cfs*54 (on ENST00000399634 / NM_001167625.1; = p.L1798Cfs*42 on NM_000719.7) | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- CADM3 | c.334A>T p.I112F (on ENST00000368125 / NM_001127173.3; = p.I146F on NM_021189.5) | Missense Mutation (SNP) | VAF 110/225 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CAMSAP1 | c.4255G>A p.G1419S | Missense Mutation (SNP) | VAF 92/95 reads (97%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPN11 | c.652G>T p.A218S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CASP5 | c.964_968del p.E322Lfs*18 | Frame Shift Del (DEL) | VAF 26/170 reads (15%) | called by mutect2, pindel
- CBFA2T2 | c.474C>G p.F158L | Missense Mutation (SNP) | VAF 26/315 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CCDC115 | c.430+8G>A | Splice Region (SNP) | VAF 180/300 reads (60%) | called by muse, mutect2, varscan2
- CCDC141 | c.3800C>A p.P1267Q | Missense Mutation (SNP) | VAF 80/295 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- CD1B | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 143/466 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CD22 | c.1180T>C p.Y394H | Missense Mutation (SNP) | VAF 89/113 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CD300LD | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 203/212 reads (96%) | called by muse, mutect2, varscan2
- CDC16 | c.1556T>G p.L519R | Missense Mutation (SNP) | VAF 73/307 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- CECR2 | c.3969_3988del p.N1323Kfs*102 (on ENST00000342247 / NM_001290047.2; = p.N1139Kfs*102 on NM_001290046.1) | Frame Shift Del (DEL) | VAF 49/194 reads (25%) | called by mutect2, pindel, varscan2
- CELF5 | c.105G>T p.Q35H | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP135 | c.1720dup p.A574Gfs*4 | Frame Shift Ins (INS) | VAF 65/327 reads (20%) | called by mutect2, pindel, varscan2
- CHRM1 | c.320T>A p.V107E | Missense Mutation (SNP) | VAF 119/217 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CLASP1 | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 88/311 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLEC4D | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 86/363 reads (24%) | called by muse, mutect2, varscan2
- CLEC4F | c.1157C>A p.A386D | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CLIP2 | c.2372A>T p.E791V | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CNTN3 | c.773A>T p.Q258L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- COBL | c.2820C>A p.H940Q | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT tolerated (0.59); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL6A3 | c.5330G>C p.G1777A | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A5 | c.2888G>T p.G963V | Missense Mutation (SNP) | VAF 75/442 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- COL6A5 | c.7027C>T p.P2343S (on ENST00000312481; = p.P2339S on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 151/323 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- CPNE4 | c.180+1G>C p.X60_splice | Splice Site (SNP) | VAF 24/102 reads (24%) | called by muse, mutect2, varscan2
- CPS1 | c.1659A>T p.K553N | Missense Mutation (SNP) | VAF 81/245 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CXCL9 | c.110dup p.N37Kfs*14 | Frame Shift Ins (INS) | VAF 72/597 reads (12%) | called by mutect2, pindel, varscan2
- DAAM2 | c.2763C>G p.S921R (on ENST00000274867 / NM_001201427.2; = p.S920R on NM_015345.3) | Missense Mutation (SNP) | VAF 86/215 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- DCAF8L1 | c.1306A>T p.N436Y | Missense Mutation (SNP) | VAF 44/297 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCC | c.1711G>T p.G571* | Nonsense Mutation (SNP) | VAF 166/562 reads (30%) | called by muse, mutect2, varscan2
- DCPS | c.965G>A p.R322K | Missense Mutation (SNP) | VAF 84/227 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- DDIT4 | c.322C>G p.R108G | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- DENND2B | c.1183G>T p.E395* | Nonsense Mutation (SNP) | VAF 189/200 reads (95%) | called by muse, mutect2, varscan2
- DHX15 | c.2102T>G p.V701G | Missense Mutation (SNP) | VAF 219/239 reads (92%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- DISP3 | c.290C>A p.P97Q | Missense Mutation (SNP) | VAF 11/248 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2
- DMD | c.4534C>A p.L1512M | Missense Mutation (SNP) | VAF 79/483 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- DNAH3 | c.12235C>T p.L4079F | Missense Mutation (SNP) | VAF 68/276 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAJC21 | c.239A>T p.E80V | Missense Mutation (SNP) | VAF 121/675 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- DOCK10 | c.6073G>C p.E2025Q | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DPY19L1 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 76/277 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DPYSL5 | c.373T>A p.C125S | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DST | c.18763A>G p.R6255G (on ENST00000361203 / NM_001374722.1; = p.R3952G on NM_015548.5) | Missense Mutation (SNP) | VAF 17/235 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2
- DYNC2H1 | c.7338G>T p.L2446F | Missense Mutation (SNP) | VAF 79/333 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- EAF2 | c.542A>C p.D181A | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.335); called by muse, mutect2
- ECSCR | c.151A>C p.N51H | Missense Mutation (SNP) | VAF 107/114 reads (94%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EEF1A2 | c.509T>A p.I170N | Missense Mutation (SNP) | VAF 176/316 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- EEF1AKMT4-ECE2 | c.995A>G p.D332G | Missense Mutation (SNP) | VAF 127/306 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- EGFL7 | c.432G>C p.R144S | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- EHBP1 | c.3328G>C p.E1110Q | Missense Mutation (SNP) | VAF 79/328 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EIF5B | c.1013A>T p.K338I | Missense Mutation (SNP) | VAF 77/320 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- EML6 | c.4867G>T p.G1623C | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ENO2 | c.218T>A p.I73N | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ENTHD1 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ESPL1 | c.4447G>C p.E1483Q | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- EZH1 | c.1829G>T p.G610V | Missense Mutation (SNP) | VAF 37/38 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- F13A1 | c.798G>A p.M266I | Missense Mutation (SNP) | VAF 620/815 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- FBXO10 | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 112/822 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- FPR1 | c.203_204del p.A68Gfs*3 | Frame Shift Del (DEL) | VAF 33/163 reads (20%) | called by mutect2, pindel, varscan2
- FRMPD1 | c.1084A>T p.M362L | Missense Mutation (SNP) | VAF 106/192 reads (55%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- FSIP2 | c.14302G>T p.V4768F | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- FUT10 | c.1009A>G p.I337V | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- GALNT14 | c.992T>G p.V331G | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- GJA9 | c.1402C>A p.P468T | Missense Mutation (SNP) | VAF 89/303 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- GJD2 | c.557A>T p.K186I | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GOLGA3 | c.688G>T p.A230S | Missense Mutation (SNP) | VAF 144/290 reads (50%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GOLGA6L2 | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 48/114 reads (42%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- GOLPH3L | c.440_444delinsA p.W147Yfs*9 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by pindel, varscan2*
- GRAMD4 | c.457A>C p.N153H | Missense Mutation (SNP) | VAF 72/128 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, varscan2
- GRID2 | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 247/385 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- GRIN2B | c.2137G>T p.G713C | Missense Mutation (SNP) | VAF 131/587 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- HELQ | c.3199-2A>T p.X1067_splice | Splice Site (SNP) | VAF 136/490 reads (28%) | called by muse, mutect2, varscan2
- HELZ2 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 53/170 reads (31%) | called by muse, mutect2, varscan2
- HOXC11 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 81/338 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTR3D | c.743C>T p.A248V (on ENST00000382489 / NM_001163646.2; = p.A75V on NM_182537.3) | Missense Mutation (SNP) | VAF 149/597 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IFI44L | c.1020G>T p.K340N | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- IGKV2D-30 | c.281C>A p.T94N | Missense Mutation (SNP) | VAF 252/455 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- IGSF10 | c.2294del p.K765Rfs*13 | Frame Shift Del (DEL) | VAF 181/550 reads (33%) | called by mutect2, pindel, varscan2
- IQGAP2 | c.3790C>G p.P1264A | Missense Mutation (SNP) | VAF 74/80 reads (93%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- IQUB | c.1071C>A p.F357L | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNA4 | c.1155G>T p.E385D | Missense Mutation (SNP) | VAF 111/213 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KCND2 | c.815C>A p.P272H | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNJ3 | c.1308A>T p.K436N | Missense Mutation (SNP) | VAF 77/552 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF2C | c.1510A>C p.S504R | Missense Mutation (SNP) | VAF 72/225 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- KIR2DL4 | c.985T>G p.S329A (on ENST00000396284; = p.S255A on NM_001080770.2) | Missense Mutation (SNP) | VAF 312/641 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- KIRREL2 | c.1842C>G p.S614R | Missense Mutation (SNP) | VAF 94/138 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KIRREL2 | c.2077T>A p.Y693N | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KLHL12 | c.1338C>G p.Y446* | Nonsense Mutation (SNP) | VAF 116/288 reads (40%) | called by muse, mutect2, varscan2
- KMT2D | c.9342_9354del p.L3115Sfs*23 | Frame Shift Del (DEL) | VAF 24/56 reads (43%) | called by mutect2, pindel, varscan2
- KRTAP13-4 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 306/313 reads (98%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- L1TD1 | c.234del p.A79Qfs*3 | Frame Shift Del (DEL) | VAF 84/154 reads (55%) | called by mutect2, pindel, varscan2
- LCP2 | c.1501A>G p.I501V | Missense Mutation (SNP) | VAF 106/115 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, varscan2
- LDLRAD2 | c.391T>A p.C131S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LEPROT | c.287G>T p.W96L | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LILRB2 | c.431G>A p.C144Y | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LILRB4 | c.796G>T p.V266L | Missense Mutation (SNP) | VAF 78/416 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- LITAF | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 49/71 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- LMF2 | c.1809del p.L604Yfs*53 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- LRFN2 | c.1727A>T p.Y576F | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- LRP6 | c.1684A>C p.S562R | Missense Mutation (SNP) | VAF 89/442 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC71 | c.1264C>A p.P422T | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated (0.61); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MAGEB3 | c.598A>C p.K200Q | Missense Mutation (SNP) | VAF 250/301 reads (83%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCF2L | c.2408G>T p.G803V (on ENST00000375608; = p.G771V on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- MDH1B | c.1053-2A>T p.X351_splice | Splice Site (SNP) | VAF 57/148 reads (39%) | called by muse, mutect2, varscan2
- MDN1 | c.432G>T p.K144N | Missense Mutation (SNP) | VAF 219/392 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- MGAT4C | c.76G>T p.V26L | Missense Mutation (SNP) | VAF 76/256 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- MIB1 | c.36del p.V14Lfs*5 | Frame Shift Del (DEL) | VAF 42/78 reads (54%) | called by mutect2, pindel, varscan2
- MID2 | c.791T>A p.L264Q | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MKLN1 | c.16del p.A6Lfs*31 | Frame Shift Del (DEL) | VAF 36/132 reads (27%) | called by mutect2, pindel, varscan2
- MOGAT3 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MON2 | c.3451C>T p.Q1151* | Nonsense Mutation (SNP) | VAF 40/168 reads (24%) | called by muse, mutect2, varscan2
- MROH7 | c.783A>T p.K261N | Missense Mutation (SNP) | VAF 104/176 reads (59%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- MRPS9 | c.302A>C p.Q101P | Missense Mutation (SNP) | VAF 153/242 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- MSX2 | c.576C>A p.N192K | Missense Mutation (SNP) | VAF 239/260 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC16 | c.19493C>A p.S6498* | Nonsense Mutation (SNP) | VAF 46/88 reads (52%) | called by muse, mutect2, varscan2
- MUC6 | c.1134C>G p.T378= | Splice Region (SNP) | VAF 69/75 reads (92%) | called by muse, mutect2, varscan2
- MYBPHL | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- MYH6 | c.4096G>C p.A1366P | Missense Mutation (SNP) | VAF 56/249 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MYO16 | c.3294C>G p.F1098L | Missense Mutation (SNP) | VAF 171/178 reads (96%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO5B | c.2480G>T p.R827M | Missense Mutation (SNP) | VAF 270/452 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- NAT8 | c.451C>G p.Q151E | Missense Mutation (SNP) | VAF 61/205 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- NCAN | c.2155G>T p.A719S | Missense Mutation (SNP) | VAF 77/153 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NGB | c.202G>T p.V68L | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2
- NLRP3 | c.2395G>C p.V799L | Missense Mutation (SNP) | VAF 100/314 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- NLRP5 | c.1942C>A p.P648T | Missense Mutation (SNP) | VAF 99/127 reads (78%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOP14 | c.2426_2435dup p.F813Gfs*29 | Frame Shift Ins (INS) | VAF 30/120 reads (25%) | called by mutect2, varscan2
- NOSTRIN | c.27+1G>C p.X9_splice | Splice Site (SNP) | VAF 183/326 reads (56%) | called by muse, mutect2, varscan2
- NPAT | c.1449A>G p.I483M | Missense Mutation (SNP) | VAF 137/442 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NPC1 | c.788T>G p.L263R | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- NR0B1 | c.66A>T p.Q22H | Missense Mutation (SNP) | VAF 90/113 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NRK | c.1037T>C p.F346S | Missense Mutation (SNP) | VAF 32/39 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- NRXN3 | c.1799C>A p.T600N (on ENST00000335750 / NM_001330195.2; = p.T227N on NM_004796.6) | Missense Mutation (SNP) | VAF 72/389 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NT5C1A | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- NUP210L | c.879A>G p.I293M | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- OR2B3 | c.53C>A p.S18* | Nonsense Mutation (SNP) | VAF 61/111 reads (55%) | called by muse, mutect2, varscan2
- OR2M5 | c.70C>A p.H24N | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- OR2W1 | c.384G>T p.K128N | Missense Mutation (SNP) | VAF 57/249 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- OR2Z1 | c.780G>T p.M260I | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- OR2Z1 | c.781G>T p.V261L | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR5M8 | c.715A>C p.T239P | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR6B3 | c.583G>C p.A195P | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR8S1 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 111/231 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- OSBPL3 | c.2141A>T p.D714V | Missense Mutation (SNP) | VAF 71/249 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- P2RY2 | c.219C>A p.F73L | Missense Mutation (SNP) | VAF 141/232 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- PARP10 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, varscan2
- PCDH12 | c.3037G>A p.E1013K | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2
- PDE3A | c.1815T>A p.S605R | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PHGDH | c.411+1G>T p.X137_splice | Splice Site (SNP) | VAF 82/356 reads (23%) | called by muse, mutect2, varscan2
- PIEZO1 | c.3967A>T p.R1323W | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKHD1L1 | c.12112C>A p.L4038I | Missense Mutation (SNP) | VAF 36/329 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PKHD1L1 | c.12113T>C p.L4038P | Missense Mutation (SNP) | VAF 36/330 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PLXNA3 | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 171/404 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- POLR3GL | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- PPP2R3B | c.1352G>A p.G451E | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- PRAMEF17 | c.1071G>T p.K357N | Missense Mutation (SNP) | VAF 99/315 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PRAMEF17 | c.1072G>T p.D358Y | Missense Mutation (SNP) | VAF 101/315 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- PREX2 | c.4531C>A p.L1511M | Missense Mutation (SNP) | VAF 45/365 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- PRKAB1 | c.260dup p.G88Rfs*15 | Frame Shift Ins (INS) | VAF 21/111 reads (19%) | called by mutect2, pindel, varscan2
- PRPS2 | c.666G>T p.M222I | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRRC2C | c.455G>A p.G152E (on ENST00000367742; = p.G150E on NM_015172.4) | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTCHD4 | c.1598G>A p.S533N | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PTGS2 | c.1329G>T p.Q443H | Missense Mutation (SNP) | VAF 101/555 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PTPRQ | c.2167G>A p.E723K (on ENST00000616559; = p.E681K on NM_001145026.2) | Missense Mutation (SNP) | VAF 234/487 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- RAB27B | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RAB27B | c.620A>T p.D207V | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM47 | c.1110C>A p.D370E | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- RBM47 | c.1108G>T p.D370Y | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT deleterious (0.03); PolyPhen benign (0.282); called by muse, mutect2
- RGPD2 | c.3809T>A p.V1270E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by mutect2, varscan2
- RGS22 | c.3630C>A p.Y1210* | Nonsense Mutation (SNP) | VAF 25/196 reads (13%) | called by muse, mutect2, varscan2
- RHOG | c.461A>T p.Y154F | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- RHPN1 | c.1012G>T p.V338F | Missense Mutation (SNP) | VAF 140/184 reads (76%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIMBP2 | c.840C>A p.N280K | Missense Mutation (SNP) | VAF 88/203 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- RIMS1 | c.2195C>T p.P732L | Missense Mutation (SNP) | VAF 142/265 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF144A | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 46/203 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RPH3A | c.884G>T p.G295V (on ENST00000389385 / NM_001143854.2; = p.G291V on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 156/286 reads (55%) | SIFT tolerated (0.39); PolyPhen benign (0.186); called by muse, varscan2
- RPS6KA3 | c.44T>G p.V15G | Missense Mutation (SNP) | VAF 72/430 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- RXFP1 | c.1876C>T p.L626F | Missense Mutation (SNP) | VAF 85/91 reads (93%) | SIFT tolerated (0.08); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- SCEL | c.1557C>G p.I519M (on ENST00000349847 / NM_144777.3; = p.I499M on NM_003843.4) | Missense Mutation (SNP) | VAF 92/99 reads (93%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- SEL1L2 | c.1199A>G p.K400R | Missense Mutation (SNP) | VAF 248/599 reads (41%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SEMA3E | c.34del p.L12Cfs*30 | Frame Shift Del (DEL) | VAF 132/510 reads (26%) | called by mutect2, pindel, varscan2
- SERPINA10 | c.58C>A p.P20T | Missense Mutation (SNP) | VAF 47/253 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SERPINB7 | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SERPINB8 | c.503A>G p.K168R | Missense Mutation (SNP) | VAF 177/272 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- SHROOM4 | c.2982_2984delinsAA p.S994Rfs*38 | Frame Shift Del (DEL) | VAF 102/203 reads (50%) | called by pindel, varscan2*
- SLC13A2 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SLC35F2 | c.327G>T p.W109C | Missense Mutation (SNP) | VAF 111/200 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC35G2 | c.1059G>T p.L353F | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- SLC37A3 | c.8G>T p.W3L | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC39A3 | c.148T>C p.F50L | Missense Mutation (SNP) | VAF 81/182 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- SLC9A6 | c.1177A>T p.I393F | Missense Mutation (SNP) | VAF 144/154 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLCO1A2 | c.1469C>G p.S490* | Nonsense Mutation (SNP) | VAF 56/228 reads (25%) | called by muse, mutect2, varscan2
- SMARCA2 | c.1635G>A p.W545* | Nonsense Mutation (SNP) | VAF 44/424 reads (10%) | called by muse, mutect2, varscan2
- SMOC2 | c.715G>A p.E239K (on ENST00000356284 / NM_001166412.2; = p.E250K on NM_022138.3) | Missense Mutation (SNP) | VAF 45/324 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SMOC2 | c.716A>T p.E239V (on ENST00000356284 / NM_001166412.2; = p.E250V on NM_022138.3) | Missense Mutation (SNP) | VAF 45/329 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SNX17 | c.185A>G p.K62R | Missense Mutation (SNP) | VAF 128/503 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- SOGA3 | c.1862A>T p.D621V | Missense Mutation (SNP) | VAF 61/250 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SORL1 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 39/233 reads (17%) | called by muse, mutect2, varscan2
- SPATA31A6 | c.1649G>T p.G550V | Missense Mutation (SNP) | VAF 168/1430 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.138); called by mutect2, varscan2
- SPINT2 | c.462G>T p.E154D | Missense Mutation (SNP) | VAF 260/351 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- SPO11 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 114/310 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SSTR4 | c.994C>T p.L332F | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ST6GALNAC2 | c.545T>G p.V182G | Missense Mutation (SNP) | VAF 90/94 reads (96%) | PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- STAB2 | c.2901G>T p.L967F | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SVIL | c.6643T>G p.*2215Gext*42 (on ENST00000355867 / NM_021738.3; = p.*1789Gext*42 on NM_003174.3 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
- TAAR2 | c.351G>T p.K117N (on ENST00000367931 / NM_001033080.1; = p.K72N on NM_014626.3) | Missense Mutation (SNP) | VAF 153/307 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAF1 | c.3576dup p.D1193* (on ENST00000373790 / NM_138923.4; = p.D1214* on NM_004606.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 7/65 reads (11%) | called by mutect2, varscan2
- TAGAP | c.1511T>C p.I504T | Missense Mutation (SNP) | VAF 80/308 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- TBL2 | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 51/183 reads (28%) | called by muse, mutect2, varscan2
- TCP11X2 | c.945C>G p.D315E | Missense Mutation (SNP) | VAF 85/179 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, varscan2
- TDRD6 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TECPR1 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TENM4 | c.3042C>A p.S1014R | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TEX15 | c.3181A>T p.K1061* (on ENST00000256246; = p.K1444* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 42/110 reads (38%) | called by muse, mutect2, varscan2
- TFE3 | c.229A>T p.S77C | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- TIAM1 | c.1816G>T p.V606F | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.165); called by muse, varscan2
- TIAM2 | c.5147T>C p.V1716A (on ENST00000529824; = p.V1687A on NM_012454.3) | Missense Mutation (SNP) | VAF 21/597 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- TNN | c.1687G>T p.V563L | Missense Mutation (SNP) | VAF 218/507 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- TPH2 | c.879C>G p.Y293* | Nonsense Mutation (SNP) | VAF 172/431 reads (40%) | called by muse, mutect2, varscan2
- TPO | c.1517C>A p.A506D | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TREML4 | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 69/319 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- TREX2 | c.184G>T p.G62W (on ENST00000334497; = p.G19W on NM_080701.3) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TRIM55 | c.1156G>T p.A386S | Missense Mutation (SNP) | VAF 62/412 reads (15%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPM6 | c.962G>T p.R321M | Missense Mutation (SNP) | VAF 78/171 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, varscan2
- TSNAXIP1 | c.484_485del p.K162Efs*2 | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | called by mutect2, pindel, varscan2
- TTC17 | c.3309del p.A1104Hfs*9 | Frame Shift Del (DEL) | VAF 50/357 reads (14%) | called by mutect2, pindel, varscan2
- TTN | c.15812G>C p.S5271T (on ENST00000591111; = p.S4344T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/194 reads (20%) | PolyPhen benign (0.014); called by muse, varscan2
- TTN | c.11755C>A p.P3919T (on ENST00000591111; = p.P3873T on NM_003319.4) | Missense Mutation (SNP) | VAF 35/118 reads (30%) | called by muse, mutect2, varscan2
- UBE3A | c.1980G>T p.Q660H | Missense Mutation (SNP) | VAF 119/237 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- UGT2A3 | c.1192C>A p.L398I | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- ULBP1 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- UNC80 | c.9232C>G p.Q3078E | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- URB1 | c.3479T>A p.L1160Q | Missense Mutation (SNP) | VAF 119/257 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- USP21 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 182/412 reads (44%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- USP25 | c.1712C>G p.S571C | Missense Mutation (SNP) | VAF 17/233 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, mutect2
- USP9X | c.4825-1G>C p.X1609_splice | Splice Site (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- VCP | c.2004G>T p.K668N | Missense Mutation (SNP) | VAF 122/384 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- VCP | c.2002A>T p.K668* | Nonsense Mutation (SNP) | VAF 122/380 reads (32%) | called by muse, mutect2
- XKR4 | c.1386T>A p.F462L | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- YEATS2 | c.3635A>T p.N1212I | Missense Mutation (SNP) | VAF 235/570 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- YIPF5 | c.587G>C p.S196T | Missense Mutation (SNP) | VAF 91/94 reads (97%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZBBX | c.1523A>T p.E508V | Missense Mutation (SNP) | VAF 82/160 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- ZBTB20 | c.773A>G p.E258G (on ENST00000474710 / NM_001164342.2; = p.E185G on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/65 reads (97%) | SIFT tolerated (0.24); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- ZBTB3 | c.626C>A p.A209E | Missense Mutation (SNP) | VAF 54/271 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ZCCHC8 | c.1737T>G p.D579E | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZDBF2 | c.3838C>A p.P1280T | Missense Mutation (SNP) | VAF 100/171 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZDHHC17 | c.160G>C p.D54H | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- ZMAT4 | c.630A>G p.I210M | Missense Mutation (SNP) | VAF 306/394 reads (78%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- ZNF175 | c.666G>C p.Q222H | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF528 | c.1003A>G p.S335G | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- ZNF792 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 52/278 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZNF804A | c.2035A>G p.T679A | Missense Mutation (SNP) | VAF 63/86 reads (73%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZXDC | c.1348A>G p.K450E | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- AAMP | c.126C>T p.D42= | Silent (SNP) | VAF 53/208 reads (25%) | called by muse, mutect2, varscan2
- ADAM19 | c.2490G>A p.S830= | Silent (SNP) | VAF 71/81 reads (88%) | catalogued as rs764968777, COSV57427459; called by muse, mutect2, varscan2
- ADGRE2 | c.369T>C p.C123= | Silent (SNP) | VAF 37/60 reads (62%) | called by muse, mutect2, varscan2
- ADGRF5 | c.1431G>A p.P477= | Silent (SNP) | VAF 66/371 reads (18%) | catalogued as rs748771069, COSV51936916; called by muse, varscan2
- ADGRG4 | c.2625A>C p.A875= | Silent (SNP) | VAF 78/84 reads (93%) | called by muse, mutect2, varscan2
- AFTPH | c.2001T>C p.D667= | Silent (SNP) | VAF 34/172 reads (20%) | called by muse, mutect2, varscan2
- AMER2 | c.972C>A p.A324= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- ANKRD30B | c.394C>T p.L132= | Silent (SNP) | VAF 135/220 reads (61%) | catalogued as rs747990388; called by muse, mutect2, varscan2
- ANKRD30B | c.945C>A p.A315= | Silent (SNP) | VAF 196/342 reads (57%) | catalogued as COSV62811748, COSV62816026; called by muse, varscan2
- ARID1B | c.6555G>T p.A2185= | Silent (SNP) | VAF 18/21 reads (86%) | catalogued as COSV99273031; called by muse, mutect2, varscan2
- ARL6IP4 | c.966G>T p.P322= (on ENST00000315580 / NM_018694.3; = p.P303= on NM_016638.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/50 reads (54%) | called by muse, mutect2, varscan2
- BAZ2A | c.1926G>A p.P642= | Silent (SNP) | VAF 70/218 reads (32%) | catalogued as rs562319546; called by muse, varscan2
- BBS10 | c.324G>A p.L108= | Silent (SNP) | VAF 111/210 reads (53%) | called by muse, mutect2, varscan2
- BTD | c.1332G>T p.G444= | Silent (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- CACNA1C | c.3072C>T p.V1024= | Silent (SNP) | VAF 66/372 reads (18%) | catalogued as rs566310000, COSV59738474; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNA1F | c.5598C>T p.G1866= | Silent (SNP) | VAF 31/158 reads (20%) | called by muse, mutect2, varscan2
- CACNA1S | c.432C>A p.V144= | Silent (SNP) | VAF 132/366 reads (36%) | called by muse, mutect2, varscan2
- CADM2 | c.249C>A p.S83= (on ENST00000407528 / NM_001167674.2; = p.S85= on NM_153184.4) | Silent (SNP) | VAF 87/91 reads (96%) | called by muse, mutect2, varscan2
- CDH2 | c.270G>C p.V90= | Silent (SNP) | VAF 135/530 reads (25%) | called by muse, mutect2, varscan2
- CDH8 | c.2277C>T p.L759= | Silent (SNP) | VAF 85/188 reads (45%) | called by muse, mutect2, varscan2
- CEL | c.915G>T p.L305= (on ENST00000673714; = p.L302= on NM_001807.6) | Silent (SNP) | VAF 65/291 reads (22%) | called by muse, mutect2, varscan2
- CELF4 | c.1356G>C p.P452= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV100610954; called by muse, mutect2, varscan2
- CFAP221 | c.2295G>A p.E765= | Silent (SNP) | VAF 45/218 reads (21%) | catalogued as rs1426713728; called by muse, mutect2, varscan2
- CFAP54 | c.4926C>T p.A1642= | Silent (SNP) | VAF 150/371 reads (40%) | called by muse, mutect2, varscan2
- CLK3 | c.753C>T p.T251= (on ENST00000395066 / NM_001130028.1; = p.T103= on NM_003992.4) | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as rs1218322061; called by muse, mutect2, varscan2
- CNTNAP2 | c.2196C>T p.I732= | Silent (SNP) | VAF 96/308 reads (31%) | catalogued as rs769830314, COSV62192120, COSV62206510; called by muse, mutect2, varscan2
- CRACD | c.1782C>A p.T594= | Silent (SNP) | VAF 81/169 reads (48%) | called by muse, mutect2, varscan2
- CTNND2 | c.18G>T p.P6= | Silent (SNP) | VAF 108/158 reads (68%) | called by muse, mutect2, varscan2
- DAGLB | c.1026G>A p.R342= | Silent (SNP) | VAF 44/179 reads (25%) | catalogued as rs1444177453; called by muse, mutect2, varscan2
- DAZL | c.468C>A p.T156= | Silent (SNP) | VAF 53/157 reads (34%) | catalogued as rs761163000; called by muse, mutect2, varscan2
- DMRTB1 | c.789C>T p.Y263= | Silent (SNP) | VAF 61/203 reads (30%) | catalogued as COSV65113299; called by muse, mutect2, varscan2
- DNAH5 | c.5127A>G p.K1709= | Silent (SNP) | VAF 283/482 reads (59%) | called by muse, mutect2, varscan2
- DPYSL2 | c.1167C>G p.A389= | Silent (SNP) | VAF 66/146 reads (45%) | called by muse, mutect2, varscan2
- EGLN3 | c.630C>A p.V210= | Silent (SNP) | VAF 76/350 reads (22%) | called by muse, mutect2, varscan2
- ELAVL2 | c.975A>C p.T325= | Silent (SNP) | VAF 106/500 reads (21%) | called by muse, mutect2, varscan2
- EPHB1 | c.165C>A p.I55= | Silent (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- FILIP1 | c.3243T>G p.T1081= | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as rs778327637; called by muse, mutect2, varscan2
- FKBP15 | c.738G>T p.L246= | Silent (SNP) | VAF 49/56 reads (88%) | called by muse, mutect2, varscan2
- FNDC1 | c.3294G>T p.A1098= | Silent (SNP) | VAF 25/40 reads (63%) | catalogued as rs1163677489; called by muse, mutect2, varscan2
- FOXG1 | c.1317G>C p.A439= | Silent (SNP) | VAF 178/247 reads (72%) | catalogued as COSV57399276; called by muse, mutect2, varscan2
- FSIP2 | c.2758C>T p.L920= | Silent (SNP) | VAF 131/202 reads (65%) | catalogued as rs1417651431; called by muse, mutect2, varscan2
- FUT9 | c.141G>A p.V47= | Silent (SNP) | VAF 67/204 reads (33%) | called by muse, mutect2, varscan2
- GLP1R | c.558C>A p.S186= | Silent (SNP) | VAF 35/145 reads (24%) | called by muse, mutect2, varscan2
- GLRA3 | c.285C>A p.I95= | Silent (SNP) | VAF 121/130 reads (93%) | called by muse, mutect2, varscan2
- GNA13 | c.930A>G p.L310= | Silent (SNP) | VAF 172/181 reads (95%) | catalogued as rs941409424; called by muse, mutect2, varscan2
- GPIHBP1 | c.438C>G p.V146= | Silent (SNP) | VAF 151/205 reads (74%) | catalogued as rs776022117; called by muse, mutect2, varscan2
- GPR89A | c.957C>G p.V319= | Silent (SNP) | VAF 56/178 reads (31%) | called by muse, mutect2, varscan2
- GRIP1 | c.981G>A p.Q327= | Silent (SNP) | VAF 115/312 reads (37%) | called by muse, mutect2, varscan2
- GRM8 | c.1884G>T p.G628= | Silent (SNP) | VAF 70/190 reads (37%) | catalogued as COSV58841588; called by muse, mutect2, varscan2
- HOXA5 | c.321C>A p.A107= | Silent (SNP) | VAF 64/97 reads (66%) | called by muse, mutect2, varscan2
- HRC | c.66C>A p.L22= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV53255188; called by muse, mutect2, varscan2
- HSPA6 | c.777G>A p.K259= | Silent (SNP) | VAF 51/261 reads (20%) | called by muse, mutect2, varscan2
- HTR1E | c.936G>A p.L312= | Silent (SNP) | VAF 85/129 reads (66%) | catalogued as rs113308093; called by muse, mutect2, varscan2
- IGLV3-9 | c.171G>A p.K57= | Silent (SNP) | VAF 263/454 reads (58%) | catalogued as rs781175411; called by muse, mutect2, varscan2
- INSYN2B | c.306T>C p.S102= | Silent (SNP) | VAF 50/56 reads (89%) | called by muse, mutect2, varscan2
- IQGAP1 | c.4935C>T p.L1645= | Silent (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- IQGAP3 | c.3489A>G p.T1163= | Silent (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- KCNH8 | c.81C>T p.S27= | Silent (SNP) | VAF 39/80 reads (49%) | called by muse, mutect2, varscan2
- KDM4C | c.2031A>G p.T677= | Silent (SNP) | VAF 48/289 reads (17%) | catalogued as COSV67183149; called by muse, mutect2, varscan2
- KIAA1210 | c.3624C>T p.S1208= | Silent (SNP) | VAF 85/163 reads (52%) | called by muse, mutect2, varscan2
- KIAA1217 | c.3369G>A p.E1123= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV56823246; called by muse, mutect2, varscan2
- KLHL30 | c.114G>T p.L38= | Silent (SNP) | VAF 34/75 reads (45%) | called by muse, mutect2, varscan2
- LARP4 | c.2079G>A p.R693= | Silent (SNP) | VAF 107/479 reads (22%) | called by muse, mutect2, varscan2
- LDLRAD2 | c.390G>A p.L130= | Silent (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- LIFR | c.438T>G p.A146= | Silent (SNP) | VAF 86/557 reads (15%) | called by muse, mutect2, varscan2
- LMO7 | c.4779C>T p.V1593= (on ENST00000357063; = p.V1274= on NM_005358.5) | Silent (SNP) | VAF 50/55 reads (91%) | called by muse, mutect2, varscan2
- LOXHD1 | c.5460C>A p.T1820= (on ENST00000642948; = p.T1758= on NM_144612.7) | Silent (SNP) | VAF 44/159 reads (28%) | called by muse, mutect2, varscan2
- LRRC74B | c.663C>G p.L221= | Silent (SNP) | VAF 85/150 reads (57%) | called by muse, mutect2, varscan2
- MAGEB18 | c.420G>A p.K140= | Silent (SNP) | VAF 324/407 reads (80%) | catalogued as COSV57464440; called by muse, mutect2, varscan2
- MAU2 | c.9T>A p.A3= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as rs966905559; called by muse, mutect2, varscan2
- MBD5 | c.3765A>T p.P1255= | Silent (SNP) | VAF 182/525 reads (35%) | catalogued as COSV101290096; called by muse, mutect2, varscan2
- MRGPRF | c.447C>A p.A149= | Silent (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- MRGPRF | c.198C>A p.L66= | Silent (SNP) | VAF 60/324 reads (19%) | called by muse, mutect2, varscan2
- MSX2 | c.577C>A p.R193= | Silent (SNP) | VAF 232/251 reads (92%) | called by mutect2, varscan2
- MYH4 | c.3388C>A p.R1130= | Silent (SNP) | VAF 124/132 reads (94%) | catalogued as rs772548795; called by muse, mutect2, varscan2
- MYH8 | c.639C>A p.G213= | Silent (SNP) | VAF 361/391 reads (92%) | catalogued as rs758456274; called by muse, mutect2, varscan2
- MYL2 | c.15A>G p.K5= | Silent (SNP) | VAF 98/198 reads (49%) | called by muse, mutect2, varscan2
- NDRG2 | c.834G>A p.L278= (on ENST00000298687 / NM_001354570.1; = p.L264= on NM_016250.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 28/167 reads (17%) | called by muse, mutect2, varscan2
- NEDD1 | c.531A>T p.L177= | Silent (SNP) | VAF 164/356 reads (46%) | called by muse, mutect2, varscan2
- NEO1 | c.4104G>A p.P1368= | Silent (SNP) | VAF 40/103 reads (39%) | catalogued as rs200012151; called by muse, varscan2
- NOTCH1 | c.2004G>A p.P668= | Silent (SNP) | VAF 59/127 reads (46%) | catalogued as rs746470497; called by muse, mutect2, varscan2
- NR2E1 | c.693A>G p.A231= | Silent (SNP) | VAF 275/456 reads (60%) | called by muse, mutect2, varscan2
- NRXN3 | c.1800T>A p.T600= (on ENST00000335750 / NM_001330195.2; = p.T227= on NM_004796.6) | Silent (SNP) | VAF 70/382 reads (18%) | called by muse, mutect2, varscan2
- OR10H1 | c.249C>A p.A83= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV58470691; called by muse, mutect2, varscan2
- OR12D3 | c.222G>C p.V74= | Silent (SNP) | VAF 71/111 reads (64%) | catalogued as COSV65826940; called by muse, mutect2, varscan2
- OR1L4 | c.630C>G p.T210= | Silent (SNP) | VAF 152/354 reads (43%) | called by muse, varscan2
- OR2A25 | c.264C>A p.A88= | Silent (SNP) | VAF 175/308 reads (57%) | called by muse, mutect2, varscan2
- PARPBP | c.102A>T p.A34= | Silent (SNP) | VAF 90/529 reads (17%) | called by muse, mutect2, varscan2
- PCDHA12 | c.2184C>T p.T728= | Silent (SNP) | VAF 109/112 reads (97%) | catalogued as rs782196097, COSV56482972; called by muse, mutect2, varscan2
- PIK3C2G | c.729G>T p.T243= | Silent (SNP) | VAF 92/133 reads (69%) | called by muse, mutect2, varscan2
- PKD1L1 | c.3747T>C p.F1249= | Silent (SNP) | VAF 77/130 reads (59%) | called by muse, mutect2, varscan2
- POM121L12 | c.771C>A p.V257= | Silent (SNP) | VAF 61/120 reads (51%) | called by muse, mutect2, varscan2
- PTPN13 | c.2928C>A p.A976= | Silent (SNP) | VAF 114/733 reads (16%) | catalogued as rs938864074; called by muse, varscan2
- PURG | c.957A>T p.T319= | Silent (SNP) | VAF 63/134 reads (47%) | called by muse, mutect2, varscan2
- PXDNL | c.4284G>T p.V1428= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs1563355642; called by muse, mutect2, varscan2
- RBBP8 | c.2394G>T p.V798= | Silent (SNP) | VAF 128/473 reads (27%) | called by muse, mutect2, varscan2
- RHEX | c.486T>A p.S162= | Silent (SNP) | VAF 131/310 reads (42%) | called by muse, mutect2, varscan2
- RXFP3 | c.1221C>A p.I407= | Silent (SNP) | VAF 135/220 reads (61%) | catalogued as COSV57504408, COSV57508152; called by muse, mutect2, varscan2
- SCRT1 | c.1017G>A p.A339= | Silent (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2
- SERPINB7 | c.234T>A p.S78= | Silent (SNP) | VAF 26/87 reads (30%) | called by muse, mutect2, varscan2
- SERPINB9 | c.849G>C p.V283= | Silent (SNP) | VAF 35/331 reads (11%) | called by muse, mutect2, varscan2
- SGO2 | c.2076A>G p.Q692= | Silent (SNP) | VAF 78/339 reads (23%) | called by muse, mutect2, varscan2
- SIRT7 | c.1200G>T p.T400= | Silent (SNP) | VAF 162/171 reads (95%) | catalogued as rs374568755; called by muse, mutect2, varscan2
- SLAMF1 | c.225G>A p.E75= | Silent (SNP) | VAF 102/448 reads (23%) | catalogued as rs763037948, COSV52502079; called by muse, mutect2, varscan2
- SLC18B1 | c.870A>G p.L290= | Silent (SNP) | VAF 146/272 reads (54%) | catalogued as rs149512313, COSV51594527; called by muse, mutect2, varscan2
- SLC26A7 | c.573G>T p.V191= | Silent (SNP) | VAF 65/460 reads (14%) | called by muse, mutect2, varscan2
- SLC9A9 | c.63G>C p.A21= | Silent (SNP) | VAF 101/223 reads (45%) | called by muse, mutect2, varscan2
- SLITRK1 | c.990C>T p.S330= | Silent (SNP) | VAF 40/102 reads (39%) | called by muse, mutect2, varscan2
- SORCS1 | c.768G>A p.L256= | Silent (SNP) | VAF 127/138 reads (92%) | catalogued as rs775365753, COSV53853967; called by muse, mutect2, varscan2
- SPATA3 | c.225C>A p.P75= | Silent (SNP) | VAF 73/151 reads (48%) | catalogued as COSV101330919; called by muse, mutect2, varscan2
- SPATA31A1 | c.3552A>G p.P1184= | Silent (SNP) | VAF 215/1294 reads (17%) | called by muse, mutect2, varscan2
- STARD8 | c.1401G>A p.L467= | Silent (SNP) | VAF 47/52 reads (90%) | catalogued as rs1169159897; called by muse, mutect2, varscan2
- TBC1D22B | c.714G>A p.L238= | Silent (SNP) | VAF 67/218 reads (31%) | called by muse, mutect2, varscan2
- TBX10 | c.1101G>T p.G367= | Silent (SNP) | VAF 56/189 reads (30%) | catalogued as rs748480424; called by muse, mutect2, varscan2
- TCP11 | c.183G>A p.K61= (on ENST00000512012; = p.K56= on NM_001261817.2) | Silent (SNP) | VAF 51/233 reads (22%) | catalogued as rs763226033; called by muse, mutect2, varscan2
- THSD1 | c.618T>C p.C206= | Silent (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- TIGAR | c.138G>T p.L46= | Silent (SNP) | VAF 65/131 reads (50%) | called by muse, mutect2, varscan2
- TMEM134 | c.99T>C p.F33= | Silent (SNP) | VAF 29/172 reads (17%) | called by muse, mutect2, varscan2
- TMEM67 | c.2298C>T p.F766= | Silent (SNP) | VAF 46/278 reads (17%) | catalogued as rs372104198; called by muse, mutect2, varscan2
- TPH2 | c.300G>A p.R100= | Silent (SNP) | VAF 151/333 reads (45%) | catalogued as rs767461365, COSV61592724, COSV61593860; called by muse, mutect2, varscan2
- TRIM48 | c.39C>G p.T13= | Silent (SNP) | VAF 145/431 reads (34%) | called by muse, mutect2, varscan2
- TRMO | c.1248G>A p.E416= | Silent (SNP) | VAF 92/260 reads (35%) | called by muse, mutect2, varscan2
- TSGA13 | c.822C>A p.I274= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as COSV58406515; called by muse, mutect2
- TTC6 | c.489G>A p.A163= | Silent (SNP) | VAF 29/133 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.38235A>T p.G12745= (on ENST00000591111; = p.G5321= on NM_003319.4) | Silent (SNP) | VAF 50/155 reads (32%) | called by muse, mutect2, varscan2
- TUBA1C | c.519G>T p.P173= | Silent (SNP) | VAF 71/304 reads (23%) | catalogued as COSV56510450; called by muse, mutect2, varscan2
- TXLNB | c.645G>A p.E215= | Silent (SNP) | VAF 81/210 reads (39%) | called by muse, mutect2, varscan2
- U2SURP | c.489A>G p.R163= | Silent (SNP) | VAF 36/232 reads (16%) | called by muse, mutect2, varscan2
- UBA1 | c.1134G>C p.L378= | Silent (SNP) | VAF 175/229 reads (76%) | called by muse, mutect2, varscan2
- UGT2B7 | c.375G>A p.K125= | Silent (SNP) | VAF 50/254 reads (20%) | called by muse, mutect2, varscan2
- UHRF1 | c.1173G>A p.S391= (on ENST00000612630 / NM_001290050.1; = p.S404= on NM_013282.4) | Silent (SNP) | VAF 32/58 reads (55%) | catalogued as rs753965332; called by muse, mutect2, varscan2
- ULBP3 | c.42G>C p.A14= | Silent (SNP) | VAF 32/63 reads (51%) | called by muse, mutect2, varscan2
- USHBP1 | c.612C>T p.I204= | Silent (SNP) | VAF 29/40 reads (73%) | called by muse, mutect2, varscan2
- USP35 | c.201G>A p.V67= | Silent (SNP) | VAF 42/92 reads (46%) | called by muse, mutect2, varscan2
- UTS2R | c.705C>A p.A235= | Silent (SNP) | VAF 58/59 reads (98%) | called by muse, mutect2, varscan2
- WDR7 | c.4365G>T p.A1455= | Silent (SNP) | VAF 107/185 reads (58%) | catalogued as rs547450912, COSV54349017, COSV54360228; called by muse, mutect2, varscan2
- ZNF585A | c.1422A>C p.A474= (on ENST00000292841 / NM_001288800.2; = p.A419= on NM_152655.3) | Silent (SNP) | VAF 51/219 reads (23%) | called by muse, mutect2, varscan2
- ZNF624 | c.102C>A p.T34= | Silent (SNP) | VAF 93/207 reads (45%) | called by muse, mutect2, varscan2
- ZNF676 | c.171G>A p.E57= (on ENST00000650058; = p.E25= on NM_001001411.3) | Silent (SNP) | VAF 70/188 reads (37%) | called by muse, mutect2, varscan2
- ZNF775 | c.1008G>C p.P336= | Silent (SNP) | VAF 65/227 reads (29%) | catalogued as COSV100301394; called by muse, mutect2, varscan2
- AC107023.1 | n.26-7108G>T | Intron (SNP) | VAF 160/341 reads (47%) | called by muse, mutect2, varscan2
- AC136759.1 | n.683G>T | RNA (SNP) | VAF 202/485 reads (42%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821605 T>A | 3'Flank (SNP) | VAF 199/214 reads (93%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.976T>C | RNA (SNP) | VAF 7/27 reads (26%) | catalogued as rs767762706; called by muse, mutect2, varscan2
- AP002008.2 | n.1423G>T | RNA (SNP) | VAF 45/160 reads (28%) | catalogued as rs754032227; called by muse, mutect2, varscan2
- ASCC3 | c.801+21T>C | Intron (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- B3GALT5-AS1 | n.657C>T | RNA (SNP) | VAF 289/304 reads (95%) | catalogued as COSV61594595; called by muse, mutect2, varscan2
- C2CD6 | c.1581+3172A>C | Intron (SNP) | VAF 26/87 reads (30%) | called by muse, mutect2, varscan2
- C2orf72 | c.*54C>A | 3'UTR (SNP) | VAF 64/138 reads (46%) | called by muse, mutect2, varscan2
- C4orf50 | c.-954C>A | 5'UTR (SNP) | VAF 95/144 reads (66%) | called by mutect2, varscan2
- C6orf118 | c.1303-12C>A | Intron (SNP) | VAF 79/111 reads (71%) | called by muse, mutect2, varscan2
- CCDC120 | c.-56G>T | 5'UTR (SNP) | VAF 224/287 reads (78%) | called by muse, mutect2, varscan2
- CETN3 | c.461-2403G>A | Intron (SNP) | VAF 85/192 reads (44%) | catalogued as rs1433855281; called by muse, mutect2, varscan2
- CLK2P1 | n.765G>C | RNA (SNP) | VAF 222/340 reads (65%) | called by muse, mutect2, varscan2
- CLPSL1 | c.*30C>G | 3'UTR (SNP) | VAF 97/404 reads (24%) | called by muse, mutect2, varscan2
- COL28A1 | c.1998+923G>T | Intron (SNP) | VAF 31/152 reads (20%) | called by muse, mutect2, varscan2
- CUL5 | c.-22G>T | 5'UTR (SNP) | VAF 27/160 reads (17%) | catalogued as COSV101263771, COSV67609333; called by muse, mutect2, varscan2
- CYTH1 | c.23-26988G>T | Intron (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- DNAJB2 | c.352+94G>T | Intron (SNP) | VAF 37/59 reads (63%) | called by muse, mutect2, varscan2
- DYRK4 | chr12:4588954 G>T | 5'Flank (SNP) | VAF 92/226 reads (41%) | called by muse, mutect2, varscan2
- DYRK4 | chr12:4588955 G>T | 5'Flank (SNP) | VAF 94/231 reads (41%) | called by muse, mutect2, varscan2
- EYS | c.1767-7304C>T | Intron (SNP) | VAF 175/521 reads (34%) | catalogued as rs775043754, COSV65458754; called by muse, mutect2, varscan2
- FAM193A | c.-219G>C | 5'UTR (SNP) | VAF 38/51 reads (75%) | called by muse, mutect2, varscan2
- FAM205BP | n.1261A>G | RNA (SNP) | VAF 47/598 reads (8%) | called by muse, mutect2
- FRRS1 | c.1596+13C>G | Intron (SNP) | VAF 35/139 reads (25%) | called by muse, mutect2, varscan2
- GBA2 | c.-491A>T | 5'UTR (SNP) | VAF 8/34 reads (24%) | called by muse, varscan2
- GFAP | c.-2G>A | 5'UTR (SNP) | VAF 31/147 reads (21%) | catalogued as rs1188890875; called by muse, mutect2, varscan2
- GNB1 | c.57+15G>T | Intron (SNP) | VAF 85/120 reads (71%) | called by muse, mutect2, varscan2
- GOSR2 | chr17:46940587 G>A | 3'Flank (SNP) | VAF 118/384 reads (31%) | called by muse, mutect2, varscan2
- GRM8 | c.727+30272T>C | Intron (SNP) | VAF 100/159 reads (63%) | catalogued as rs910714627; called by muse, mutect2, varscan2
- H3-2 | c.*356C>A | 3'UTR (SNP) | VAF 31/197 reads (16%) | called by muse, mutect2, varscan2
- HLA-DPB1 | c.101-139C>A | Intron (SNP) | VAF 183/322 reads (57%) | called by muse, mutect2, varscan2
- HSP90AB3P | n.323C>G | RNA (SNP) | VAF 45/265 reads (17%) | called by muse, mutect2, varscan2
- HSP90B1 | c.-21G>C | 5'UTR (SNP) | VAF 54/110 reads (49%) | called by muse, mutect2, varscan2
- HTR5A | chr7:155069223 A>G | 5'Flank (SNP) | VAF 89/168 reads (53%) | catalogued as rs1244816456; called by muse, mutect2, varscan2
- JRK | c.*5478_*5479delinsT | 3'UTR (DEL) | VAF 37/350 reads (11%) | called by pindel, varscan2*
- KCNK12 | c.*8509T>C | 3'UTR (SNP) | VAF 53/201 reads (26%) | catalogued as rs1319009941; called by muse, mutect2, varscan2
- LAD1 | c.39-1798G>T | Intron (SNP) | VAF 34/239 reads (14%) | called by muse, mutect2, varscan2
- LDHA | chr11:18394595 C>T | 5'Flank (SNP) | VAF 43/377 reads (11%) | catalogued as rs1016376653; called by muse, mutect2, varscan2
- LINC00470 | n.1431A>T | RNA (SNP) | VAF 196/344 reads (57%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+660C>G | Intron (SNP) | VAF 150/175 reads (86%) | called by muse, mutect2, varscan2
- MDGA2 | c.281-41491A>T | Intron (SNP) | VAF 63/280 reads (23%) | called by muse, mutect2, varscan2
- MFSD10 | c.1252+24G>A | Intron (SNP) | VAF 20/82 reads (24%) | catalogued as rs1470933601; called by muse, mutect2, varscan2
- MGST3 | c.-7-27C>T | Intron (SNP) | VAF 146/363 reads (40%) | catalogued as rs539663851; called by muse, mutect2, varscan2
- MICU2 | c.598-1189G>C | Intron (SNP) | VAF 28/31 reads (90%) | called by muse, mutect2, varscan2
- MID1 | c.757-5734G>A | Intron (SNP) | VAF 69/305 reads (23%) | called by muse, mutect2, varscan2
- MIR29B2CHG | n.2C>T | RNA (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- MSR1 | c.1034-528A>T | Intron (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40561014 C>T | 5'Flank (SNP) | VAF 37/292 reads (13%) | catalogued as rs267603458; called by muse, mutect2, varscan2
- NBPF7 | n.176A>T | RNA (SNP) | VAF 224/344 reads (65%) | called by muse, mutect2, varscan2
- NRXN1 | c.3719-1422A>G | Intron (SNP) | VAF 134/513 reads (26%) | called by muse, mutect2, varscan2
- OR2P1P | chr6:29076330 C>A | 5'Flank (SNP) | VAF 50/130 reads (38%) | called by muse, mutect2, varscan2
- PMEPA1 | chr20:57710414 G>A | 5'Flank (SNP) | VAF 30/83 reads (36%) | called by muse, mutect2, varscan2
- PMFBP1 | c.-24G>A | 5'UTR (SNP) | VAF 111/122 reads (91%) | called by muse, mutect2, varscan2
- PPAT | c.403-678A>T | Intron (SNP) | VAF 63/124 reads (51%) | called by muse, mutect2, varscan2
- PPP2R1B | c.*39T>G | 3'UTR (SNP) | VAF 53/150 reads (35%) | called by muse, mutect2, varscan2
- PRSS1 | c.201-23A>T | Intron (SNP) | VAF 71/264 reads (27%) | called by muse, mutect2, varscan2
- PTHLH | c.-23+49C>G | Intron (SNP) | VAF 70/371 reads (19%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158747 C>A | 5'Flank (SNP) | VAF 49/191 reads (26%) | catalogued as rs112567409; called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159510 G>T | 5'Flank (SNP) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- RNU6-104P | chr8:43300537 T>A | 5'Flank (SNP) | VAF 325/421 reads (77%) | catalogued as rs1485669521; called by muse, mutect2, varscan2
- SKP2 | c.1061+173A>T | Intron (SNP) | VAF 14/146 reads (10%) | catalogued as rs889142403; called by muse, mutect2
- SLC1A2 | chr11:35419877 C>A | 5'Flank (SNP) | VAF 26/33 reads (79%) | called by muse, mutect2, varscan2
- SPTLC3 | c.303+111T>A | Intron (SNP) | VAF 17/113 reads (15%) | called by muse, mutect2, varscan2
- TAF4B | c.1832+1703G>T | Intron (SNP) | VAF 35/119 reads (29%) | called by muse, mutect2, varscan2
- TMEM71 | c.752+29G>A | Intron (SNP) | VAF 69/637 reads (11%) | catalogued as rs1481132434; called by muse, mutect2, varscan2
- TPSD1 | chr16:1262597 G>T | 3'Flank (SNP) | VAF 92/191 reads (48%) | called by muse, mutect2, varscan2
- TRBV23OR9-2 | n.250G>T | RNA (SNP) | VAF 114/365 reads (31%) | called by muse, mutect2, varscan2
- VAPB | c.*3893A>G | 3'UTR (SNP) | VAF 155/991 reads (16%) | called by muse, mutect2, varscan2
- ZAP70 | c.838-67G>T | Intron (SNP) | VAF 31/107 reads (29%) | called by muse, mutect2, varscan2
- ZNF134 | c.-146G>T | 5'UTR (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- ZNF849P | n.858C>T | RNA (SNP) | VAF 89/223 reads (40%) | catalogued as rs1258316311; called by muse, mutect2, varscan2
